Somatic mutation profile of tumor specimen TCGA-AC-A7VB-01A (aliquot TCGA-AC-A7VB-01A-11D-A351-09) from TCGA case TCGA-AC-A7VB, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 51.5 years (18,806 days).
Specimen TCGA-AC-A7VB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7edf5f9b-c516-402f-97a2-d75ab9cbdb5d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AC-A7VB-10A (Blood Derived Normal), aliquot TCGA-AC-A7VB-10A-01D-A351-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/773de9d7-3e1f-46c2-912f-d6118071077f

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 13, Silent 7, Frame Shift Del 2, Nonsense Mutation 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL6A3 | c.3736C>T p.P1246S | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.62); PolyPhen benign (0.038); catalogued as COSV99801592; called by muse, mutect2, varscan2
- DOCK8 | c.2482G>A p.A828T | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs138519226; called by muse, mutect2, varscan2
- GJA1 | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.432); catalogued as rs774210184, CM161897, COSV56996979; called by muse, mutect2, varscan2
- LRFN4 | c.1860C>A p.C620* | Nonsense Mutation (SNP) | VAF 16/34 reads (47%) | catalogued as COSV100540895; called by muse, mutect2, varscan2
- MRGPRX1 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.797); catalogued as rs780543634, COSV57105973; called by muse, mutect2, varscan2
- NBEAL2 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV52763451, COSV99436879; called by muse, mutect2, varscan2
- NDUFS5 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.116); catalogued as rs368988409, COSV65892286; called by muse, mutect2, varscan2
- PCDHA11 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100254614; called by muse, mutect2, varscan2
- PCDHAC2 | c.2563G>T p.E855* | Nonsense Mutation (SNP) | VAF 18/50 reads (36%) | catalogued as COSV99162784; called by muse, mutect2, varscan2
- PLEKHA6 | c.2302+1G>A p.X768_splice | Splice Site (SNP) | VAF 23/54 reads (43%) | catalogued as COSV99692811; called by muse, mutect2, varscan2
- TFDP3 | c.1031C>A p.A344E | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV100033546; called by muse, mutect2, varscan2
- TLR7 | c.2464G>A p.G822S | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV101028152; called by muse, mutect2, varscan2
- TMC2 | c.1678C>T p.P560S | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.049); catalogued as rs1441322726, COSV100727994; called by muse, mutect2, varscan2
- ZNF215 | c.1454C>T p.T485M | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs545734774, COSV99549948; called by muse, mutect2, varscan2
- LHX1 | c.505A>T p.N169Y | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- MRGBP | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- PDE7A | c.1001_1008del p.R334Ifs*3 (on ENST00000401827 / NM_001242318.3; = p.R308Ifs*3 on NM_002603.4) | Frame Shift Del (DEL) | VAF 18/67 reads (27%) | called by mutect2, pindel, varscan2
- SNRNP200 | c.3621_3622delinsA p.D1207Efs*26 | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | called by pindel, varscan2*
- HOXB6 | c.630G>A p.A210= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as COSV53311955, COSV99494750; called by muse, mutect2, varscan2
- IGHV5-51 | c.87G>A p.E29= | Silent (SNP) | VAF 73/128 reads (57%) | catalogued as rs190944050; called by muse, mutect2
- KCNT2 | c.2883T>C p.T961= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV99656830; called by muse, mutect2, varscan2
- LAP3 | c.1167C>T p.A389= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs375594380; called by muse, mutect2, varscan2
- OR52A5 | c.606C>T p.G202= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV100263574; called by muse, mutect2, varscan2
- PAPPA2 | c.1887C>T p.H629= | Silent (SNP) | VAF 20/34 reads (59%) | catalogued as rs759601604, COSV62779278; called by muse, mutect2, varscan2
- TAPBP | c.333C>A p.P111= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs561857093, COSV101418761; called by muse, mutect2, varscan2
